Somatic mutation profile of tumor specimen C3L-03260-01 (aliquot CPT0189250006) from CPTAC case C3L-03260, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 75.0 years (27,394 days).
Specimen C3L-03260-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc3d35b0-9b9c-4115-af86-023e7e2c158e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03260-31 (Blood Derived Normal), aliquot CPT0190200002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb72978d-6532-4d90-9422-80c6504dd030

The open-access MAF lists 69 somatic variants for this specimen: 37 protein-altering or splice-affecting, 20 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 20, RNA 4, Intron 3, Frame Shift Del 3, Nonsense Mutation 3, 3'UTR 3, 5'UTR 1, In Frame Del 1, 3'Flank 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GABRG2 | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057520498, COSV62719464; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PDGFRA | c.2526_2537del p.I843_D846del | In Frame Del (DEL) | VAF 113/445 reads (25%) | catalogued as rs1553906053; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.634+1G>A p.X212_splice | Splice Site (SNP) | VAF 72/102 reads (71%) | hotspot (GDC flag); catalogued as CS110219, CS1314438, COSV64295775, COSV64297457, COSV64302278; called by muse, mutect2, varscan2
- ATP4A | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs779456771, COSV52869103; called by muse, mutect2, varscan2
- CLDN8 | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 61/175 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs555436710; called by muse, mutect2, varscan2
- FGA | c.1102G>A p.G368R | Missense Mutation (SNP) | VAF 78/229 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs139005577; called by muse, mutect2, varscan2
- HAMP | c.90+5G>C | Splice Region (SNP) | VAF 241/814 reads (30%) | catalogued as rs1034720579; called by muse, mutect2, varscan2
- IHH | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 172/465 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.825); catalogued as rs1244499290; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNG3 | c.788C>T p.T263M | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs148581980; called by muse, mutect2, varscan2
- MAPK7 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 137/356 reads (38%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.683); catalogued as rs780101862, COSV55189720; called by muse, mutect2, varscan2
- MC3R | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 164/552 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs760254173, COSV54763308, COSV54763803; called by muse, mutect2
- MLLT6 | c.3022G>C p.G1008R | Missense Mutation (SNP) | VAF 151/624 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.508); catalogued as rs1397222744; called by muse, mutect2, varscan2
- MPP3 | c.1475G>A p.R492K | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs1212833436; called by muse, mutect2, varscan2
- MYH14 | c.5278G>A p.E1760K | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs771246753; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STK3 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 84/259 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as rs200907713, COSV101372645; called by muse, mutect2, varscan2
- TRPV6 | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs748594853, COSV63890443; called by muse, mutect2, varscan2
- TUBB4A | c.1057G>A p.V353M | Missense Mutation (SNP) | VAF 296/838 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.914); catalogued as rs771498039; called by muse, varscan2
- TUBB4A | c.1024G>A p.V342M | Missense Mutation (SNP) | VAF 290/838 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.989); catalogued as rs754036226; called by muse, varscan2
- ZSCAN10 | c.1604G>A p.R535Q (on ENST00000252463; = p.R590Q on NM_032805.3) | Missense Mutation (SNP) | VAF 111/311 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs773346032; called by muse, mutect2, varscan2
- ATP6V1H | c.1406A>G p.K469R | Missense Mutation (SNP) | VAF 78/294 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CDKN2A | c.153dup p.M52Hfs*68 | Frame Shift Ins (INS) | VAF 158/369 reads (43%) | called by mutect2, pindel, varscan2
- CNTNAP1 | c.4036A>G p.T1346A | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DAB2 | c.1141del p.V381Yfs*32 | Frame Shift Del (DEL) | VAF 142/488 reads (29%) | called by mutect2, pindel, varscan2
- DNAH9 | c.345C>G p.S115R | Missense Mutation (SNP) | VAF 67/177 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- EYS | c.4834T>A p.S1612T | Missense Mutation (SNP) | VAF 72/237 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- GOLGA8O | c.43A>T p.K15* | Nonsense Mutation (SNP) | VAF 42/478 reads (9%) | called by muse, varscan2
- GPNMB | c.536C>G p.T179R | Missense Mutation (SNP) | VAF 93/465 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- IBA57 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 113/294 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, varscan2
- MEIOC | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- MSN | c.395C>A p.S132Y | Missense Mutation (SNP) | VAF 327/628 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- MTMR14 | c.1630del p.L544Cfs*16 | Frame Shift Del (DEL) | VAF 50/153 reads (33%) | called by mutect2, pindel, varscan2
- OR4D2 | c.373G>T p.A125S | Missense Mutation (SNP) | VAF 268/781 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OTOGL | c.6238G>T p.E2080* (on ENST00000547103; = p.E2071* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 20/59 reads (34%) | called by muse, mutect2, varscan2
- PNPLA1 | c.1276T>G p.S426A (on ENST00000394571 / NM_001374623.1; = p.S331A on NM_173676.2) | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); called by muse, mutect2
- SETD1B | c.581del p.T194Mfs*21 | Frame Shift Del (DEL) | VAF 90/202 reads (45%) | called by mutect2, pindel, varscan2
- TAF1L | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 58/100 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- TMPRSS7 | c.1677C>A p.C559* (on ENST00000452346; = p.C433* on NM_001042575.2) | Nonsense Mutation (SNP) | VAF 33/76 reads (43%) | called by muse, mutect2, varscan2
- ACTL9 | c.600C>T p.H200= | Silent (SNP) | VAF 153/458 reads (33%) | catalogued as COSV61004826; called by muse, mutect2, varscan2
- ANKRD28 | c.345T>A p.A115= | Silent (SNP) | VAF 80/256 reads (31%) | called by muse, mutect2, varscan2
- ATP7A | c.3123G>T p.V1041= | Silent (SNP) | VAF 85/176 reads (48%) | called by muse, mutect2, varscan2
- CAMKV | c.1422C>T p.G474= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as rs199584092; called by muse, mutect2, varscan2
- CAPNS1 | c.141C>T p.G47= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as rs17879825; called by muse, mutect2
- CCDC51 | c.204G>A p.G68= | Silent (SNP) | VAF 154/471 reads (33%) | called by muse, mutect2, varscan2
- CCNP | c.324C>T p.R108= | Silent (SNP) | VAF 162/469 reads (35%) | catalogued as rs1325883795; called by muse, mutect2, varscan2
- CMSS1 | c.588G>A p.A196= | Silent (SNP) | VAF 87/252 reads (35%) | catalogued as rs750330461, COSV70436440; called by muse, mutect2, varscan2
- COL8A2 | c.1644C>T p.N548= | Silent (SNP) | VAF 32/87 reads (37%) | catalogued as rs561219162, COSV57441555; called by muse, mutect2, varscan2
- DSG1 | c.1602C>T p.N534= | Silent (SNP) | VAF 43/147 reads (29%) | catalogued as rs751362602; called by muse, mutect2, varscan2
- GOLGA8O | c.42G>A p.K14= | Silent (SNP) | VAF 42/480 reads (9%) | called by muse, varscan2
- LRAT | c.330G>A p.V110= | Silent (SNP) | VAF 173/487 reads (36%) | called by muse, mutect2, varscan2
- NLRP8 | c.3102C>T p.P1034= | Silent (SNP) | VAF 111/339 reads (33%) | catalogued as rs142444217; called by muse, mutect2, varscan2
- NPTX2 | c.984C>T p.D328= | Silent (SNP) | VAF 108/452 reads (24%) | catalogued as rs781445701, COSV55719214; called by muse, mutect2, varscan2
- PCDHA2 | c.2199G>A p.A733= | Silent (SNP) | VAF 275/754 reads (36%) | catalogued as COSV65367530; called by muse, mutect2, varscan2
- PTCH2 | c.1110C>T p.N370= | Silent (SNP) | VAF 179/491 reads (36%) | catalogued as rs575126296, COSV64710205; called by muse, mutect2, varscan2
- SDK1 | c.5721A>G p.R1907= | Silent (SNP) | VAF 135/557 reads (24%) | called by muse, mutect2, varscan2
- STRIP1 | c.1221G>A p.P407= | Silent (SNP) | VAF 99/290 reads (34%) | catalogued as rs749167658; called by muse, mutect2, varscan2
- TCF20 | c.5202G>A p.P1734= | Silent (SNP) | VAF 152/405 reads (38%) | called by muse, mutect2, varscan2
- TLL2 | c.1791C>T p.G597= | Silent (SNP) | VAF 351/496 reads (71%) | called by muse, mutect2, varscan2
- AC136604.1 | chr5:179652427 C>T | 3'Flank (SNP) | VAF 118/317 reads (37%) | called by muse, mutect2, varscan2
- BAGE2 | n.257G>T | RNA (SNP) | VAF 36/1322 reads (3%) | called by muse, mutect2
- CCSER1 | c.2094+23092G>A | Intron (SNP) | VAF 118/328 reads (36%) | catalogued as rs151072829; called by muse, mutect2, varscan2
- GFAP | c.*25G>A | 3'UTR (SNP) | VAF 151/407 reads (37%) | called by muse, mutect2, varscan2
- MAGEA5 | n.26A>C | RNA (SNP) | VAF 78/166 reads (47%) | called by muse, mutect2, varscan2
- MYADML | n.687C>T | RNA (SNP) | VAF 153/393 reads (39%) | catalogued as rs766121343; called by muse, mutect2
- PEG10 | c.*613del | 3'UTR (DEL) | VAF 57/208 reads (27%) | catalogued as COSV71788420; called by mutect2, pindel, varscan2
- PKD1L2 | n.2718C>T | RNA (SNP) | VAF 119/309 reads (39%) | catalogued as rs542299761; called by muse, mutect2, varscan2
- RGS9 | c.1407+20G>A | Intron (SNP) | VAF 151/389 reads (39%) | catalogued as rs375069570; called by muse, mutect2, varscan2
- THRB | c.-12G>T | 5'UTR (SNP) | VAF 58/171 reads (34%) | called by muse, mutect2, varscan2
- TMEM18 | c.57+46_57+48dup | Intron (INS) | VAF 215/666 reads (32%) | called by mutect2, pindel, varscan2
- XIAP | c.*4270del | 3'UTR (DEL) | VAF 11/51 reads (22%) | called by pindel, varscan2
